Somatic mutation profile of tumor specimen MP2PRT-PANYGB-TMP1-A (aliquot MP2PRT-PANYGB-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANYGB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,788 days).
Specimen MP2PRT-PANYGB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5392b1fd-0175-4f1c-b2c9-14f5385424e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANYGB-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANYGB-NM1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84e24d24-b04d-4205-b7eb-fc990b9b50a5

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS15 | c.2407G>T p.E803* | Nonsense Mutation (SNP) | VAF 351/727 reads (48%) | catalogued as COSV54509100; called by muse, mutect2, varscan2
- MPDZ | c.3814G>T p.D1272Y | Missense Mutation (SNP) | VAF 162/326 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV59916797; called by muse, mutect2, varscan2
- KRTAP22-2 | c.100T>A p.Y34N | Missense Mutation (SNP) | VAF 39/345 reads (11%) | PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- LONRF3 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 316/852 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ALOX12B | c.1497C>T p.R499= | Silent (SNP) | VAF 278/624 reads (45%) | catalogued as rs371016744, COSV100047733; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NOL6 | c.2163G>T p.L721= | Silent (SNP) | VAF 27/666 reads (4%) | called by muse, mutect2
- OGT | c.105A>T p.G35= | Silent (SNP) | VAF 156/499 reads (31%) | called by muse, mutect2, varscan2
- PCDHGB5 | c.1554C>T p.Y518= | Silent (SNP) | VAF 65/673 reads (10%) | called by muse, mutect2
